Gene-level copy-number profile of tumor specimen TCGA-QQ-A5VB-01A from TCGA case TCGA-QQ-A5VB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 53.8 years (19,654 days).
Specimen TCGA-QQ-A5VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4133ffe3-9263-41d5-958d-6078bab4891e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A5VB-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0354155-ee84-45bd-a7c7-9c92f696bf0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 4,063; copy number 2: 31,575; copy number 3: 16,987; copy number 4: 4,495; copy number 5: 1,915; copy number 6: 437; copy number 7: 134; copy number 8: 147; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A5VB-01A-11D-A36I-01): tumor purity 0.45, ploidy 3.26, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:83,643,602–83,725,390, 1 gene: DLG2-AS2.
- chr11:85,628,573–86,069,882, 10 genes (within-gene range 0–2): TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM.
- chr12:25,103,124–26,833,194, 37 genes (within-gene range 0–2): AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr14:44,392,531–44,507,283, 3 genes: AL161752.1, LINC02277, FSCB.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,637 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:87,620,803–88,685,204, 1 gene, copy number 6 (within-gene range 4–6): PKN2-AS1.
- chr1:88,313,153–96,696,167, 174 genes, copy number 6 (broad region; genes not listed).
- chr1:155,289,293–157,112,412, 95 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr6:69,672,757–73,198,853, 48 genes, copy number 5 (within-gene range 4–5): LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4.
- chr8:36,121,398–36,279,696, 4 genes, copy number 9: AC124290.3, MTCYBP19, MTND6P19, MTND5P41.
- chr8:46,028,804–52,745,843, 96 genes, copy number 5 (broad region; genes not listed).
- chr8:83,293,925–84,164,564, 5 genes, copy number 6: AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1.
- chr9:14,475–7,478,320, 134 genes, copy number 7 (broad region; genes not listed).
- chr9:12,098,660–14,472,407, 26 genes, copy number 6: AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1.
- chr9:60,914,407–68,644,442, 177 genes, copy number 5 (broad region; genes not listed).
- chr9:68,780,065–68,789,670, 2 genes, copy number 5: FAM122A, AL354794.2.
- chr9:86,751,297–88,803,716, 48 genes, copy number 5–6: AL159996.1, GAS1, GAS1RR, AL513318.1, CDC20P1, NFYCP2, LINC02872, AL136367.1, AL353752.1, AL353752.2, DAPK1, AL161787.1, DAPK1-IT1, CTSL, AL160279.1, CTSL3P, AL772337.4, FBP2P1, ELF2P3, NPAP1P7, CTSLP8, AL772337.2, AL772337.1, AL772337.3, SPATA31E1, SPATA31C1, AL353572.2, AL353572.3, CDK20, RNU6-86P, RPS10P3, AL353572.4, AL353572.1, SPATA31C2, AL353726.1, AL353726.2, AL451142.1, AL451142.2, RPSAP49, AL353748.3, SPIN1, AL353748.2, HNRNPA1P14, AL353748.1, NXNL2, LINC02843, AL390791.1, MIR4289.
- chr16:84,368,527–90,222,851, 209 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:30,713,275–36,829,216, 109 genes, copy number 6 (broad region; genes not listed).
- chr18:36,901,946–36,923,814, 1 gene, copy number 6: AC016493.1.
- chr19:16,574,907–17,848,071, 71 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:21,123,817–21,387,177, 14 genes, copy number 5: VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1.
- chr20:8,831,186–11,345,855, 38 genes, copy number 6: RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.
- chr20:12,865,202–13,300,651, 9 genes, copy number 6: LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1.
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,063. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
